Gene-level copy-number profile of tumor specimen C3N-05101-02 (profiled together with C3N-05101-04) from CPTAC case C3N-05101, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 76.9 years (28,084 days).
Specimen C3N-05101-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0db35c44-0cef-4548-8fda-6b00fb10c38a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-05101-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/5a7886d7-b970-4cb9-b288-94b7a14109c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,804; copy number 2: 43,248; copy number 3: 5,396; copy number 4: 6,839; copy number 5: 21; copy number 6: 1,081.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:62,105,660–62,106,049, 1 gene (within-gene range 0–1): RPS15AP17.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,102 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:56,805,336–57,020,273, 7 genes, copy number 5: CICP28, AC118758.2, AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:59,132,434–59,372,871, 1 gene, copy number 6 (within-gene range 2–6): MYO1E.
- chr15:59,206,843–59,208,588, 1 gene, copy number 6 (within-gene range 2–6): LDHAL6B.
- chr15:59,266,720–101,887,767, 1,079 genes, copy number 6 (broad region; genes not listed).
- chr21:10,413,477–13,067,033, 10 genes, copy number 5: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 1,468. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
